Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6956, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6956-01A (Primary Tumor).

[page 1 of 4]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS :

(O)(P) LEFT AND RIGHT BODY OF MANDIBLE:

INVOLVED BY INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA;
RIGHT AND LEFT LATERAL MANDIBULAR RESECTION MARGINS FREE OF TUMOR.

D:N

DIAGNOSIS :

(A) LEFT JUGULAR LYMPH NODES:

All of twelve lymph nodes, free of carcinoma.

(B) LEFT SUBMANDIBULAR TRIANGLE:

ONE OF SIX LYMPH NODES INVOLVED BY SQUAMOUS CELL CARCINOMA
(WITHOUT PERINODAL INVASION); SUBMANDIBULAR GLAND FREE OF
CARCINOMA.

(C) SUPRAOMOHYOID NECK DISSECTION:

All of nine lymph nodes and one submandibular gland, free of
carcinoma.

(D) RIGHT MENTAL NERVE:

Peripheral nerve and surrounding connective tissue, no tumor
present.

(E) NO SPECIMEN RECEIVED.

(F) MENTUM:

SQUAMOUS CELL CARCINOMA IN SKELETAL MUSCLE.

(G) TISSUE OF BONE MARROW SPACE OF MANDIBLE:

[page 2 of 4]
- FRAGMENTS OF BONE WITH SMALL FRAGMENTS OF SQUAMOUS CELL CARCINOMA.
- (H) RIGHT POSTERIOR TONGUE:
No tumor present.
- (I) RIGHT MIDDLE TONGUE:
No tumor present.
- (J) LEFT MIDDLE TONGUE:
No tumor present.
- (K) LEFT POSTERIOR TONGUE:
Focal moderate dysplasia of overlying epithelium.
- (L) NEW ANTERIOR MENTAL MARGIN:
No tumor present.
- (M) LEFT ALVEOLAR MARGIN:
No tumor present.
- (N) RIGHT ALVEOLAR MARGIN:
No tumor present.
- (O) FLOOR OF MOUTH, TONGUE, MANDIBLE:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
INVOLVING FLOOR OF MOUTH, ANTERIOR TONGUE, MENTAL SOFT TISSUE,
AND MANDIBLE. (SEE COMMENT)
- (P) ANTERIOR MANDIBLE:
Diagnosis pending decalcification.
- (Q) SOFT TISSUE, ALVEOLAR CANAL:
Peripheral nerve with fragments of bone, no tumor present.
- (R) TEETH:
Eight teeth.

COMMENT: Although an inked resection margin at the anterior floor of mouth is involved by carcinoma, the location corresponds to that of the "anterior mental margin" (negative by frozen section specimen L), and therefore does not represent a true margin. The tumor approaches a right floor of mouth margin. The right and left posterior base of tongue margins are involved by moderate dysplasia. The tumor demonstrates vascular and perineural invasion.

A supplemental report describing the mandibular resection margins will follow.

This revised report is issued to show the correct site designation for specimen L.

DIAGNOSIS .

- (L) NEW ANTERIOR MENTAL MARGIN:
No tumor present.

[page 3 of 4]
COMMENT: Although an inked resection margin at the anterior floor of mouth is involved by carcinoma, the location corresponds to that of the "anterior mental margin" (negative by frozen section specimen L), and therefore does not represent a true margin. The tumor approaches a right floor of mouth margin. The right and left posterior base of tongue margins are involved by moderate dysplasia. The tumor demonstrates vascular and perineural invasion.

A supplemental report describing the mandibular resection margins will follow.

This revised report is issued to show the correct site designation for specimen L.

DIAGNOSIS

- (A) LEFT JUGULAR LYMPH NODES:
All of twelve lymph nodes, free of carcinoma.
- (B) LEFT SUBMANDIBULAR TRIANGLE:
ONE OF SIX LYMPH NODES INVOLVED BY SQUAMOUS CELL CARCINOMA
(WITHOUT PERINODAL INVASION); SUBMANDIBULAR GLAND FREE OF
CARCINOMA.
- (C) SUPRAOMOHYOID NECK DISSECTION:
All of nine lymph nodes and one submandibular gland, free of
carcinoma.
- (D) RIGHT MENTAL NERVE:
Peripheral nerve and surrounding connective tissue, no tumor
present.
- (E) NO SPECIMEN RECEIVED.
- (F) MENTUM:
SQUAMOUS CELL CARCINOMA IN SKELETAL MUSCLE.
- (G) TISSUE OF BONE MARROW SPACE OF MANDIBLE:
FRAGMENTS OF BONE WITH SMALL FRAGMENTS OF SQUAMOUS CELL CARCINOMA.
- (H) RIGHT POSTERIOR TONGUE:
No tumor present.
- (I) RIGHT MIDDLE TONGUE:
No tumor present.
- (J) LEFT MIDDLE TONGUE:
No tumor present.
- (K) LEFT POSTERIOR TONGUE:
Focal moderate dysplasia of overlying epithelium.
- (L) NEW MARGIN:
No tumor present.
- (M) LEFT ALVEOLAR MARGIN:
No tumor present.
- (N) RIGHT ALVEOLAR MARGIN:
No tumor present.
- (O) FLOOR OF MOUTH, TONGUE, MANDIBLE:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
INVOLVING FLOOR OF MOUTH, ANTERIOR TONGUE, MENTAL SOFT TISSUE,
AND MANDIBLE. (SEE COMMENT)
- (P) ANTERIOR MANDIBLE:
Diagnosis pending decalcification.
- (Q) SOFT TISSUE, ALVEOLAR CANAL:
Peripheral nerve with fragments of bone, no tumor present.
- (R) TEETH:

[page 4 of 4]
Eight teeth.

COMMENT

A deep resection margin at the anterior floor of mouth is involved by carcinoma. The tumor approaches a right floor of mouth margin. The right and left posterior base of tongue margins are involved by moderate dysplasia. The tumor demonstrates vascular and perineural invasion.

A supplemental report describing the mandibular resection margins will follow.

SPECIMEN

- (A) LEFT JUGULAR LYMPH NODES:
- (B) LEFT SUBMANDIBULAR TRIANGLE:
- (C) SUPRAOMOHYOID NECK DISSECTION:
- (D) RIGHT MENTAL NERVE:
- (E) NO SPECIMEN RECEIVED.
- (F) MENTUM:
- (G) TISSUE OF BONE MARROW SPACE OF MANDIBLE:
- (H) RIGHT POSTERIOR TONGUE:
- (I) RIGHT MIDDLE TONGUE:
- (J) LEFT MIDDLE TONGUE:
- (K) LEFT POSTERIOR TONGUE:
- (L) NEW MARGIN:
- (M) LEFT ALVEOLAR MARGIN:
- (N) RIGHT ALVEOLAR MARGIN:
- (O) FLOOR OF MOUTH, TONGUE, MANDIBLE:
- (P) ANTERIOR MANDIBLE:
- (Q) SOFT TISSUE, ALVEOLAR CANAL:
- (R) TEETH:

SNOMED CODES

T-51200,M-80703

Source: NCI Genomic Data Commons file 56f2fe32-f82c-4b11-acba-53aa2431fcc4 (TCGA-CV-6956.9D9C0E77-B1FF-4545-AB0F-E2FEF6791760.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).